Surgical pathology report (de-identified scan), TCGA case TCGA-B3-A6W5, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B3-A6W5-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, papillary renal cell
8266/3
Site: Kidney NOS
C64.9

JW 7/25/13
JW 7/25/13

Final Surgical Pathology Report

Procedure:

Diagnosis

Right kidney, nephrectomy:

Clear cell renal cell carcinoma, with focal papillary features, nuclear grade 3, 2.5 cm with extension into the fat of the renal sinus, margins uninvolved.

Separate papillary renal cell carcinoma, nuclear grade 2, 2.8 cm, confined to the kidney, margins uninvolved.

Microscopic Description:

Microscopic examination performed.

The following template applies to the hilar mass:

Histologic type: Clear cell carcinoma with focal papillary features

Histologic grade: Fuhrman nuclear grade 3

Primary tumor (pT): The carcinoma is 2.5 cm however extends into the fat of the renal sinus, pT3

Margins of resection: negative

Regional lymph nodes (pN): none submitted, pNX

Distant metastasis (pM): cannot be evaluated by this specimen, pMX

Adrenal gland: not present

Vascular invasion: not identified

Non-neoplastic kidney: unremarkable

Other findings: none

The following template applies to the peripheral tumor

Histologic type: Papillary carcinoma

Histologic grade, Fuhrman nuclear grade 2

Primary tumor (pT): 2.8 cm, confined to the kidney, pT1

Margins of resection: uninvolved

Regional lymph nodes (pN): none submitted, pNX

Distant metastasis (pM): pMX

Adrenal gland: not present

Vascular invasion: not identified

Non-neoplastic kidney: unremarkable

Other findings: none

Specimen

Right kidney

Clinical Information

Renal cancer

Gross Description

Received fresh and subsequently fixed in formalin labeled "right kidney" is a 406 g kidney which is predominant covered with abundant yellow lobular fat measuring 15 x 11 x 5.5 cm. (Weight and measurements including fat). The specimen shows no discrete adrenal gland. There is a 4.0 cm long ureter. The specimen is bivalved to show 2.5 x 2.0 x 2.0 cm orange irregular well-circumscribed mass located at the hilum. This is within 1.2 cm of the stapled hilum. There is an additional pale yellow irregular nodular lesion measuring 2.7 cm in greatest dimension. This is well-circumscribed and does not appear to grossly invade through the capsule. This is located near the periphery of the

[page 2 of 2]
specimen, approximately 2.8 cm from the hilum and 2 cm from first described tumor. The remainder of the parenchyma is pink red, smooth and glistening with a discrete cortical medullary border. No other discrete gross lesions are identified. No lymph nodes are grossly identified in the surrounding fat. Representative sections of the specimen are submitted as follows: 1 - vascular and ureteral margins, 2 - 5- representative tumor to radial margin and normal, 6 - possible tumor to hilar margin, 7 - representative normal, 8 - 11 - representative sections of additional tumor to radial margin (capsule) and normal, 12 - representative section of normal between tumors.

Source: NCI Genomic Data Commons file edc62b49-5792-4b97-aaf8-98937403bd25 (TCGA-B3-A6W5.D45FFC62-48F3-4281-BEAF-F87E320AD6B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).